Somatic mutation profile of tumor specimen MMRF_2081_1_BM_CD138pos (aliquot MMRF_2081_1_BM_CD138pos_T1_KBS5U_L07217) from MMRF case MMRF_2081, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.4 years (25,353 days).
Specimen MMRF_2081_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bea6afb8-e43e-4a24-87c9-0e491a617268.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2081_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2081_1_PB_Whole_C2_KBS5U_L07218; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/056c13d4-1109-46ee-933c-69ec0f01e115

The open-access MAF lists 101 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 24, Intron 17, Silent 11, 5'Flank 4, Splice Site 3, Frame Shift Ins 3, RNA 2, 5'UTR 1, Nonstop Mutation 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 112/277 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATP10A | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs777738173, COSV63516773; called by muse, mutect2, varscan2
- COL23A1 | c.468C>T p.P156= | Splice Region (SNP) | VAF 77/162 reads (48%) | catalogued as rs372552040, COSV66789834; called by muse, mutect2, varscan2
- DUSP2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.595); catalogued as rs1367393590; called by muse, mutect2, varscan2
- EYA1 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779423947, COSV58164435; called by muse, mutect2, varscan2
- GGH | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as rs765922991; called by muse, mutect2, varscan2
- HMCN2 | c.9637C>T p.R3213C | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs960703225; called by muse, mutect2, varscan2
- IGLV3-1 | c.47-2A>G p.X16_splice | Splice Site (SNP) | VAF 68/70 reads (97%) | catalogued as rs181922188; called by muse, varscan2
- IGLV3-1 | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 80/82 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs774205851; called by muse, varscan2
- IGLV3-1 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 77/79 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs61731681; called by muse, mutect2, varscan2
- NXPE3 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs1446190351, COSV56292922; called by muse, mutect2
- NYAP2 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56003594; called by muse, mutect2, varscan2
- PCDHGA6 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as rs1443411888; called by muse, mutect2
- SLC45A2 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772074126; called by muse, mutect2, varscan2
- TBC1D16 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as rs894428634; called by muse, mutect2, varscan2
- VASN | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs779931971; called by muse, mutect2, varscan2
- ZFP36L1 | c.57+1G>A p.X19_splice | Splice Site (SNP) | VAF 46/102 reads (45%) | catalogued as rs563928424, COSV60544075; called by muse, mutect2, varscan2
- ZNF727 | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 124/275 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1372051478; called by muse, varscan2
- ADAMTSL1 | c.243C>G p.C81W | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADHFE1 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ADSS1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP2M1 | c.1305_*9delinsT | Nonstop Mutation (DEL) | VAF 33/47 reads (70%) | called by pindel, varscan2*
- BPIFB3 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CCDC3 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- DNAH11 | c.3750dup p.C1251Mfs*5 | Frame Shift Ins (INS) | VAF 66/166 reads (40%) | called by mutect2, pindel, varscan2
- FLG | c.4300A>C p.S1434R | Missense Mutation (SNP) | VAF 100/336 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAPVD1 | c.1172C>G p.P391R | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HECTD4 | c.12053T>A p.I4018N | Missense Mutation (SNP) | VAF 111/232 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.189); called by muse, varscan2
- HIF3A | c.139G>A p.V47I (on ENST00000377670 / NM_152795.4; = p.A26= on NM_022462.4) | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- HTRA1 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV2-70 | c.135delinsAT p.S47Lfs*5 | Frame Shift Ins (INS) | VAF 29/29 reads (100%) | called by pindel, varscan2*
- IGHV2-70D | c.135delinsAT p.S47Lfs*5 | Frame Shift Ins (INS) | VAF 11/21 reads (52%) | called by pindel, varscan2*
- PARP12 | c.1047G>C p.M349I | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PITPNA | c.743A>C p.E248A | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- PROSER2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2
- RUFY3 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- STK33 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM51 | c.563A>T p.D188V | Missense Mutation (SNP) | VAF 170/175 reads (97%) | SIFT tolerated (0.1); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- TNPO1 | c.1701+1G>A p.X567_splice | Splice Site (SNP) | VAF 98/201 reads (49%) | called by muse, mutect2, varscan2
- ZNF112 | c.150G>T p.Q50H (on ENST00000337401 / NM_001083335.2; = p.Q44H on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF831 | c.999G>C p.E333D | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- C14orf39 | c.495T>A p.I165= | Silent (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- CACNA1E | c.4764T>C p.R1588= | Silent (SNP) | VAF 56/82 reads (68%) | called by muse, mutect2, varscan2
- CANX | c.933G>A p.K311= | Silent (SNP) | VAF 94/196 reads (48%) | called by muse, mutect2, varscan2
- DAAM2 | c.2880C>A p.I960= (on ENST00000274867 / NM_001201427.2; = p.I959= on NM_015345.3) | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV51350627; called by muse, mutect2, varscan2
- IGHA2 | c.330C>T p.C110= | Silent (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- KRTAP10-5 | c.519C>T p.Y173= | Silent (SNP) | VAF 71/144 reads (49%) | catalogued as rs1369280923, COSV100554475; called by muse, mutect2, varscan2
- PCDHB13 | c.1341C>T p.N447= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs373463206, COSV53396279; called by muse, mutect2
- RNF130 | c.498G>A p.L166= | Silent (SNP) | VAF 104/199 reads (52%) | catalogued as COSV56154741; called by muse, mutect2, varscan2
- TEX14 | c.375G>A p.P125= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as rs1315153371, COSV53617394, COSV53621319; called by muse, mutect2
- TFAP2B | c.219C>A p.P73= | Silent (SNP) | VAF 70/142 reads (49%) | catalogued as COSV53825232, COSV99541028; called by muse, mutect2, varscan2
- TRABD2B | c.684C>T p.N228= | Silent (SNP) | VAF 26/31 reads (84%) | called by muse, mutect2, varscan2
- ADAM28 | c.2178+223T>C | Intron (SNP) | VAF 123/260 reads (47%) | called by muse, mutect2, varscan2
- AMACR | c.*2231T>C | 3'UTR (SNP) | VAF 53/120 reads (44%) | catalogued as rs1455030933; called by muse, mutect2, varscan2
- AMACR | c.*1344T>A | 3'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- ARFIP2 | c.*62G>A | 3'UTR (SNP) | VAF 54/132 reads (41%) | called by muse, mutect2, varscan2
- BAALC | chr8:103229168 C>A | 3'Flank (SNP) | VAF 47/124 reads (38%) | called by muse, mutect2, varscan2
- BAGE2 | n.2412G>T | RNA (SNP) | VAF 102/339 reads (30%) | called by muse, mutect2, varscan2
- BARD1 | c.1904-606C>T | Intron (SNP) | VAF 194/429 reads (45%) | called by muse, mutect2, varscan2
- C4orf33 | c.*1243C>G | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- CNTN1 | c.*227C>G | 3'UTR (SNP) | VAF 60/115 reads (52%) | called by muse, mutect2, varscan2
- CPM | c.*3902_*3903del | 3'UTR (DEL) | VAF 40/100 reads (40%) | called by mutect2, pindel, varscan2
- CPM | c.*596G>A | 3'UTR (SNP) | VAF 6/10 reads (60%) | catalogued as rs1046319290; called by muse, mutect2, varscan2
- CTSC | c.318+9281C>T | Intron (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- CYP19A1 | c.628+287G>A | Intron (SNP) | VAF 46/97 reads (47%) | catalogued as rs543529943; called by muse, mutect2, varscan2
- DDX56 | c.1567-107C>T | Intron (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- GADD45G | c.53+112C>T | Intron (SNP) | VAF 26/46 reads (57%) | called by mutect2, varscan2
- GORAB | c.*474dup | 3'UTR (INS) | VAF 66/241 reads (27%) | called by mutect2, pindel, varscan2
- GUCY1A1 | c.*1404A>T | 3'UTR (SNP) | VAF 29/30 reads (97%) | called by muse, mutect2, varscan2
- HNRNPA3P1 | n.663C>A | RNA (SNP) | VAF 144/328 reads (44%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105864795 G>A | 5'Flank (SNP) | VAF 14/14 reads (100%) | catalogued as rs544003301; called by muse, varscan2
- ITPR1 | c.7538-100G>A | Intron (SNP) | VAF 94/112 reads (84%) | catalogued as rs951219484; called by muse, mutect2, varscan2
- KRT5 | c.927+65T>A | Intron (SNP) | VAF 82/165 reads (50%) | called by muse, mutect2, varscan2
- LONRF2 | c.*9771G>A | 3'UTR (SNP) | VAF 51/101 reads (50%) | called by muse, mutect2, varscan2
- MRPL28 | c.*119G>A | 3'UTR (SNP) | VAF 55/110 reads (50%) | called by muse, mutect2, varscan2
- MYOM1 | c.2507-51T>C | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- NDUFA5 | c.*4530G>A | 3'UTR (SNP) | VAF 64/124 reads (52%) | called by muse, mutect2, varscan2
- NECTIN3 | c.*462G>A | 3'UTR (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- NKX2-8 | c.*755A>G | 3'UTR (SNP) | VAF 83/183 reads (45%) | called by muse, mutect2, varscan2
- NSUN3 | c.*1866A>G | 3'UTR (SNP) | VAF 59/122 reads (48%) | called by muse, mutect2, varscan2
- ORC3 | chr6:87590115 G>A | 5'Flank (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- OTOG | c.*170C>A | 3'UTR (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.1845+3168C>T | Intron (SNP) | VAF 7/80 reads (9%) | catalogued as rs1256969132; called by muse, mutect2
- PLEKHM3 | c.-114C>T | 5'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- POMT2 | c.817-57C>T | Intron (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- SDK1 | c.*3470G>A | 3'UTR (SNP) | VAF 42/88 reads (48%) | catalogued as rs1339063865, COSV67366913; called by muse, mutect2, varscan2
- SERPINB9 | c.*341G>A | 3'UTR (SNP) | VAF 42/98 reads (43%) | catalogued as rs1008277741; called by muse, mutect2, varscan2
- SF3B6 | chr2:24076585 G>A | 5'Flank (SNP) | VAF 10/26 reads (38%) | catalogued as rs1480441034; called by muse, mutect2
- SGSM1 | c.*762G>C | 3'UTR (SNP) | VAF 34/34 reads (100%) | called by muse, mutect2, varscan2
- SHCBP1 | c.923+27_923+30del | Intron (DEL) | VAF 8/54 reads (15%) | catalogued as rs767097078; called by pindel, varscan2
- SMIM29 | c.77+100G>A | Intron (SNP) | VAF 53/116 reads (46%) | called by muse, mutect2, varscan2
- SPINK5 | c.602+33A>T | Intron (SNP) | VAF 68/130 reads (52%) | catalogued as rs776066068; called by muse, mutect2, varscan2
- TACR2 | c.*439G>A | 3'UTR (SNP) | VAF 26/41 reads (63%) | called by muse, mutect2, varscan2
- TMEM132D | c.1444-1051G>C | Intron (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- TMEM159 | c.*106C>T | 3'UTR (SNP) | VAF 32/87 reads (37%) | catalogued as rs1045515769; called by muse, mutect2, varscan2
- TRAPPC11 | c.*716G>A | 3'UTR (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- TRPM3 | c.1154+8286A>T | Intron (SNP) | VAF 33/67 reads (49%) | catalogued as rs891918485; called by muse, mutect2, varscan2
- TUBB3 | c.278-223G>T | Intron (SNP) | VAF 34/34 reads (100%) | called by muse, mutect2, varscan2
- TUSC3 | c.*521T>C | 3'UTR (SNP) | VAF 79/162 reads (49%) | called by muse, mutect2, varscan2
- UBE2C | chr20:45812630 G>A | 5'Flank (SNP) | VAF 60/116 reads (52%) | catalogued as rs112324564; called by muse, mutect2, varscan2
- ZNF654 | c.*2192C>T | 3'UTR (SNP) | VAF 98/200 reads (49%) | called by muse, mutect2, varscan2
